Somatic mutation profile of tumor specimen TARGET-10-PARDBN-09A (aliquot TARGET-10-PARDBN-09A-01D) from TARGET case TARGET-10-PARDBN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,810 days).
Specimen TARGET-10-PARDBN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e3bb183-e7c0-4c18-92b0-7eb0aa149d17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDBN-10A (Blood Derived Normal), aliquot TARGET-10-PARDBN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51932d7-f787-435f-992d-c492858a4ae4

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 2, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APBA3 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769019461, COSV57462582; called by mutect2, varscan2
- C8orf76 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1216898876; called by muse, mutect2
- CCDC168 | c.13232G>A p.G4411E | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.088); catalogued as rs1228764304; called by muse, mutect2
- CRYAB | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs1264081192, COSV57052894; called by muse, mutect2
- DNAH5 | c.12275C>T p.A4092V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs1025759175, COSV54205901; called by muse, mutect2, varscan2
- GRM3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs967635794, COSV64468638; called by muse, mutect2, varscan2
- NRCAM | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV61030439, COSV61035172; called by muse, mutect2
- TRIM64C | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs779694861; called by muse, mutect2, varscan2
- USP9X | c.5863C>T p.R1955* | Nonsense Mutation (SNP) | VAF 68/91 reads (75%) | catalogued as COSV100198624; called by muse, mutect2, varscan2
- ADAMTS9 | c.2247T>A p.N749K | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MATR3 | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- RAB3D | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV1-69D | chr14:106762088 TGTGTC>CCCCT | Silent (DEL) | VAF 23/29 reads (79%) | called by pindel, varscan2*
- THSD7A | c.891C>T p.R297= | Silent (SNP) | VAF 70/152 reads (46%) | catalogued as rs375820480; called by muse, mutect2, varscan2
- TPK1 | c.501+123C>T | Intron (SNP) | VAF 9/15 reads (60%) | catalogued as rs568417881; called by muse, mutect2, varscan2
- ZNF737 | c.-100_-99insCCC | 5'UTR (INS) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
